Somatic mutation profile of tumor specimen ALCH-B25V-TTP1-A (aliquot ALCH-B25V-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B25V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.7 years (23,638 days).
Specimen ALCH-B25V-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 644c1216-be03-41ca-b3b4-207032dc344a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B25V-NB1-A (Blood Derived Normal), aliquot ALCH-B25V-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c8d132c-333d-4b02-a71d-cc40ca441957

The open-access MAF lists 208 somatic variants for this specimen: 147 protein-altering or splice-affecting, 41 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 41, Intron 14, Nonsense Mutation 3, Splice Site 3, 3'UTR 2, 3'Flank 2, RNA 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 79/442 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 13/204 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- ADAMTS17 | c.2153G>A p.G718D | Missense Mutation (SNP) | VAF 66/738 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs750136636, COSV51476657; called by muse, mutect2
- ADAMTSL1 | c.2693G>A p.R898H | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65892587; called by muse, mutect2, varscan2
- ADGRB2 | c.2893C>T p.R965C | Missense Mutation (SNP) | VAF 17/307 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57071881; called by muse, mutect2
- ANKRD30A | c.3517G>T p.A1173S (on ENST00000611781; = p.A1117S on NM_052997.2) | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.087); catalogued as rs1395356654; called by muse, mutect2
- CHST6 | c.910C>A p.H304N | Missense Mutation (SNP) | VAF 91/741 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV60001318; called by muse, mutect2, varscan2
- COL20A1 | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755789566, COSV58917944; called by muse, mutect2
- CSN2 | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 36/510 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV61992216; called by muse, mutect2
- CXorf58 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64857904; called by muse, mutect2, varscan2
- DCDC1 | c.5264G>T p.R1755I (on ENST00000597505 / NM_001367979.1; = p.R862I on NM_020869.3) | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100360385; called by muse, mutect2
- DDX60 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 29/529 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs747328711, COSV67098921; called by muse, mutect2
- DDX60 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 28/534 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs370438683; called by muse, mutect2
- DNAH5 | c.9225G>T p.M3075I | Missense Mutation (SNP) | VAF 53/459 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV54264386; called by muse, varscan2
- DUS1L | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs747393671, COSV100152683; called by muse, mutect2, varscan2
- FLNC | c.2239G>A p.V747I | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as rs764876916, COSV57952255; called by muse, mutect2
- FOXO4 | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as COSV99050878; called by muse, mutect2, varscan2
- GABRG2 | c.1423C>A p.H475N (on ENST00000361925 / NM_001375343.1; = p.H435N on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/483 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV100729847; called by muse, mutect2
- GRIN2B | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.948); catalogued as COSV74205199; called by muse, mutect2, varscan2
- HECTD1 | c.2434A>G p.T812A | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs758479061; called by muse, mutect2
- IRGC | c.1226C>A p.P409Q | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as rs747940145, COSV54983048; called by muse, mutect2
- ITGA4 | c.1457G>A p.C486Y | Missense Mutation (SNP) | VAF 20/361 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365814464, COSV52000057; called by muse, mutect2
- KRTAP19-1 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 45/582 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.311); catalogued as rs768003210, COSV66861041; called by muse, mutect2
- KRTAP19-8 | c.97C>G p.R33G | Missense Mutation (SNP) | VAF 52/434 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV66998473; called by muse, mutect2, varscan2
- L2HGDH | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs748747271, COSV55561030; called by muse, mutect2, varscan2
- MROH2B | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as rs1488616502; called by muse, mutect2
- NXPE4 | c.1440G>A p.M480I (on ENST00000375478 / NM_001077639.2; = p.M196I on NM_017678.3) | Missense Mutation (SNP) | VAF 35/428 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs750370150; called by muse, mutect2
- OR10A7 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.394); catalogued as rs547131558; called by muse, mutect2, varscan2
- OR4A15 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs199544134, COSV59035778, COSV59037883; called by muse, mutect2
- OR5B17 | c.718G>T p.G240C | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV100641910; called by muse, mutect2
- OR8U1 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56416665; called by muse, mutect2
- PCDH10 | c.1315G>T p.G439C | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99993421; called by muse, mutect2
- PCDH10 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99994451; called by muse, mutect2
- PCLO | c.8842C>G p.P2948A | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61666208; called by muse, mutect2, varscan2
- PDHA2 | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.106); catalogued as COSV54779955, COSV54780252; called by muse, mutect2
- PTPRD | c.5622G>T p.Q1874H | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100647953; called by muse, mutect2, varscan2
- PTPRT | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61999229; called by muse, mutect2
- SIRPB1 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs773790540; called by muse, mutect2
- SLITRK4 | c.1595C>A p.P532Q | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62023835; called by muse, mutect2, varscan2
- ST6GAL2 | c.1274C>A p.T425N | Missense Mutation (SNP) | VAF 20/244 reads (8%) | PolyPhen benign (0.411); catalogued as rs778650793; called by muse, mutect2
- TADA1 | c.427A>G p.M143V | Missense Mutation (SNP) | VAF 34/682 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs765691758; called by muse, mutect2
- TENM2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 49/598 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV72853478; called by muse, mutect2
- TMOD3 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.251); catalogued as rs754891010; called by muse, mutect2, varscan2
- TMPRSS15 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 26/428 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV53049405; called by muse, mutect2
- TOGARAM2 | c.839G>C p.R280P | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as rs1446625760; called by muse, mutect2
- TRIM49B | c.1178C>T p.T393I | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1307969779; called by muse, mutect2
- USP20 | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200854092, COSV59615085; called by muse, mutect2, varscan2
- ZNF497 | c.1165G>T p.A389S | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.055); catalogued as COSV54051826; called by muse, mutect2, varscan2
- ZNF534 | c.1549C>A p.R517S (on ENST00000332323 / NM_001143939.3; = p.R504S on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs370491316; called by muse, mutect2
- ADAMTS3 | c.2146A>T p.K716* | Nonsense Mutation (SNP) | VAF 34/390 reads (9%) | called by muse, mutect2
- AFP | c.1821G>T p.L607F | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- ALMS1 | c.9697G>T p.G3233C | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.482); called by muse, mutect2
- AMPH | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BOD1L2 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.879); called by muse, mutect2
- BPNT2 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 16/317 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by muse, mutect2
- BTBD11 | c.1264G>T p.V422L | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2
- BTN1A1 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.627); called by muse, mutect2
- C10orf120 | c.407G>C p.C136S | Missense Mutation (SNP) | VAF 24/427 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.082); called by muse, mutect2
- CCN3 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD34 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 27/443 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2
- CEP250 | c.6204G>T p.R2068S | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2
- CEP55 | c.392A>T p.Q131L | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2
- COG4 | c.1635G>C p.K545N | Missense Mutation (SNP) | VAF 56/463 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL16A1 | c.124A>G p.S42G | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- COL24A1 | c.1505C>A p.P502Q | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2
- COL24A1 | c.1137del p.Q379Hfs*6 | Frame Shift Del (DEL) | VAF 19/182 reads (10%) | called by mutect2, pindel, varscan2
- CSGALNACT2 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 15/251 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD2 | c.8632A>T p.N2878Y | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- DACH2 | c.1193G>C p.S398T | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- DCHS1 | c.599A>C p.D200A | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.111); called by muse, mutect2
- DOCK3 | c.4280C>T p.P1427L | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); called by muse, mutect2
- DSG1 | c.1074T>A p.H358Q | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- EN1 | c.836C>A p.T279K | Missense Mutation (SNP) | VAF 32/556 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- EPB41L3 | c.2878A>T p.S960C | Missense Mutation (SNP) | VAF 40/405 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- EPHA1 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ESF1 | c.121A>G p.M41V | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- FAM184B | c.950C>A p.T317N | Missense Mutation (SNP) | VAF 29/392 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.513); called by muse, mutect2
- FAT2 | c.11011C>A p.L3671I | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FBN3 | c.168-1G>A p.X56_splice | Splice Site (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- FOXL1 | c.240G>T p.M80I | Missense Mutation (SNP) | VAF 51/595 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.722); called by muse, mutect2
- GABRA4 | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 28/492 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GON4L | c.1178A>G p.D393G | Missense Mutation (SNP) | VAF 32/834 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- HDLBP | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- HEATR4 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.116); called by muse, mutect2
- HERC2 | c.7404G>T p.M2468I | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2
- HIF1AN | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGHV3-66 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 22/340 reads (6%) | called by muse, mutect2
- IRAK4 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- ITGA11 | c.547C>A p.H183N | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- KCNC2 | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNU1 | c.1689T>A p.F563L | Missense Mutation (SNP) | VAF 16/351 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- KIAA1549L | c.2050C>G p.L684V (on ENST00000321505; = p.L981V on NM_012194.3) | Missense Mutation (SNP) | VAF 37/338 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KIF27 | c.2695G>A p.D899N | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2
- KLRF1 | c.558G>T p.W186C | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LHX2 | c.178A>G p.I60V | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- LILRA6 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- LRP1B | c.4096G>T p.G1366C | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRP2 | c.1179G>T p.E393D | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.079); called by muse, mutect2
- LSM11 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAML3 | c.1274A>G p.H425R | Missense Mutation (SNP) | VAF 32/488 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, mutect2
- MDH1B | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 14/305 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- MUC3A | c.329T>C p.F110S | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- MXRA5 | c.2456C>A p.P819Q | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2
- MYOM2 | c.958+1G>A p.X320_splice | Splice Site (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- NEGR1 | c.735T>A p.C245* | Nonsense Mutation (SNP) | VAF 18/336 reads (5%) | called by muse, mutect2
- NPEPPS | c.463A>C p.K155Q | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); called by muse, varscan2
- NPY1R | c.972C>A p.N324K | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NUGGC | c.1491G>T p.E497D | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, mutect2
- NYAP2 | c.1862C>A p.A621E | Missense Mutation (SNP) | VAF 36/393 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR13C2 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH17 | c.1700C>A p.A567D | Missense Mutation (SNP) | VAF 33/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- PCMTD2 | c.996C>G p.D332E | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PDCD2L | c.511G>T p.V171F | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.013); called by muse, mutect2
- PDZRN4 | c.2786A>C p.D929A (on ENST00000402685 / NM_001164595.2; = p.D671A on NM_013377.4) | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHKA2 | c.3435G>T p.M1145I | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PKLR | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLEKHG4B | c.2349T>A p.S783R (on ENST00000283426; = p.S1139R on NM_052909.5) | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PRKD3 | c.598A>T p.I200F | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PRKG1 | c.726A>T p.E242D | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- PRL | c.28G>T p.G10W | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2
- PRR5L | c.897C>G p.I299M | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRN2 | c.2304G>T p.E768D | Missense Mutation (SNP) | VAF 24/349 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2
- RBM20 | c.545C>A p.P182H | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.866); called by muse, mutect2
- RIMKLB | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 63/434 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- RYR1 | c.4384A>T p.S1462C | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.115); called by muse, mutect2
- SCAPER | c.85A>T p.I29L | Missense Mutation (SNP) | VAF 27/304 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); called by muse, mutect2
- SDAD1 | c.535A>G p.M179V | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2
- SELENOV | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.296); called by muse, mutect2
- SLITRK5 | c.591C>G p.F197L | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- ST18 | c.2141C>G p.A714G | Missense Mutation (SNP) | VAF 11/399 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.174); called by muse, mutect2
- STAB2 | c.3618G>T p.E1206D | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYT9 | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); called by muse, mutect2
- TMEM132C | c.230T>A p.L77Q | Missense Mutation (SNP) | VAF 12/402 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM67 | c.2238A>G p.I746M | Missense Mutation (SNP) | VAF 27/279 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.079); called by muse, mutect2
- TMEM94 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMPRSS11E | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 33/441 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TNNT2 | c.545C>A p.A182D | Missense Mutation (SNP) | VAF 30/582 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2
- TRIM10 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 54/570 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- TRIM51GP | c.1327C>A p.L443I | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TSC1 | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSPAN7 | c.122A>T p.K41I | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- VIPAS39 | c.1477A>T p.N493Y | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- VIPR2 | c.749-1G>T p.X250_splice | Splice Site (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2
- VSTM2A | c.172T>C p.Y58H | Missense Mutation (SNP) | VAF 39/379 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- XKR7 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZBED5 | c.1925A>T p.H642L | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ZFHX4 | c.2081G>T p.C694F | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AGAP1 | c.2226C>T p.D742= (on ENST00000304032 / NM_001037131.3; = p.D689= on NM_014914.5) | Silent (SNP) | VAF 38/407 reads (9%) | catalogued as rs764429973; called by muse, mutect2
- AHDC1 | c.2178G>T p.R726= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs1300870104; called by muse, mutect2, varscan2
- ALG10 | c.495G>A p.L165= | Silent (SNP) | VAF 36/608 reads (6%) | catalogued as COSV56792327; called by muse, mutect2
- BTG2 | c.96G>A p.E32= | Silent (SNP) | VAF 16/407 reads (4%) | catalogued as COSV51857365; called by muse, mutect2
- CCDC82 | c.693A>G p.T231= | Silent (SNP) | VAF 42/428 reads (10%) | catalogued as COSV53592332; called by muse, mutect2
- CFAP221 | c.1893C>T p.L631= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs778281201; called by muse, mutect2, varscan2
- CNR1 | c.339C>T p.P113= | Silent (SNP) | VAF 11/254 reads (4%) | catalogued as COSV62987057; called by muse, mutect2
- DNAJC10 | c.1623C>T p.H541= | Silent (SNP) | VAF 18/321 reads (6%) | called by muse, mutect2
- ENPP1 | c.801G>A p.L267= | Silent (SNP) | VAF 16/299 reads (5%) | called by muse, mutect2
- ESPNL | c.2676C>T p.H892= | Silent (SNP) | VAF 27/194 reads (14%) | catalogued as rs557336771, COSV58035780; called by muse, mutect2, varscan2
- FCAR | c.264C>T p.D88= | Silent (SNP) | VAF 24/348 reads (7%) | called by muse, mutect2
- GOLGA8J | c.972C>A p.A324= | Silent (SNP) | VAF 54/982 reads (5%) | called by muse, mutect2
- GPM6A | c.330C>A p.I110= | Silent (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- GRIK4 | c.273G>A p.V91= | Silent (SNP) | VAF 22/266 reads (8%) | called by muse, mutect2
- GRPEL2 | c.39G>C p.V13= | Silent (SNP) | VAF 28/256 reads (11%) | called by muse, mutect2, varscan2
- IBTK | c.1080T>C p.D360= | Silent (SNP) | VAF 23/179 reads (13%) | called by muse, mutect2, varscan2
- IDUA | c.744C>T p.F248= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as rs775908560, COSV56103175; called by muse, mutect2
- ITGAX | c.1812G>T p.V604= | Silent (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
- KMO | c.1020G>A p.L340= | Silent (SNP) | VAF 24/190 reads (13%) | called by muse, mutect2
- MGAM | c.4560A>T p.A1520= | Silent (SNP) | VAF 54/697 reads (8%) | called by muse, mutect2
- MYF5 | c.354G>T p.L118= | Silent (SNP) | VAF 49/631 reads (8%) | catalogued as COSV57356917; called by muse, mutect2
- NAV2 | c.60G>A p.L20= | Silent (SNP) | VAF 32/441 reads (7%) | called by muse, mutect2
- OR2T4 | c.537C>T p.G179= | Silent (SNP) | VAF 40/542 reads (7%) | called by muse, mutect2
- OR8U1 | c.849C>A p.P283= | Silent (SNP) | VAF 22/304 reads (7%) | called by muse, mutect2
- OTOGL | c.2268G>T p.S756= (on ENST00000547103; = p.S747= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/317 reads (7%) | catalogued as COSV101509275; called by muse, mutect2
- PAPPA2 | c.1620C>A p.P540= | Silent (SNP) | VAF 13/318 reads (4%) | called by muse, mutect2
- PCDH17 | c.1701C>A p.A567= | Silent (SNP) | VAF 32/395 reads (8%) | called by muse, mutect2
- PPP1R12C | c.561C>A p.I187= | Silent (SNP) | VAF 10/89 reads (11%) | called by muse, varscan2
- RYR2 | c.13380A>G p.Q4460= | Silent (SNP) | VAF 9/254 reads (4%) | called by muse, mutect2
- SERPINA4 | c.168T>A p.A56= | Silent (SNP) | VAF 29/257 reads (11%) | called by muse, mutect2, varscan2
- SIGLEC7 | c.1053G>T p.V351= | Silent (SNP) | VAF 17/135 reads (13%) | called by muse, mutect2, varscan2
- SLC16A14 | c.657C>T p.N219= | Silent (SNP) | VAF 10/198 reads (5%) | catalogued as COSV54617753; called by muse, mutect2
- SLC5A1 | c.219C>T p.S73= | Silent (SNP) | VAF 42/546 reads (8%) | called by muse, mutect2
- SLC5A12 | c.1566C>T p.I522= | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- SMCP | c.228C>A p.T76= | Silent (SNP) | VAF 30/606 reads (5%) | called by muse, mutect2
- SMOC1 | c.1185C>A p.A395= | Silent (SNP) | VAF 27/663 reads (4%) | called by muse, mutect2
- SRPX2 | c.1365C>A p.T455= | Silent (SNP) | VAF 61/333 reads (18%) | called by muse, mutect2, varscan2
- TPSB2 | c.129C>T p.P43= | Silent (SNP) | VAF 15/210 reads (7%) | called by muse, mutect2
- TRPM7 | c.3504G>A p.K1168= | Silent (SNP) | VAF 24/193 reads (12%) | called by muse, mutect2, varscan2
- TSC1 | c.792G>T p.L264= | Silent (SNP) | VAF 29/283 reads (10%) | called by muse, mutect2, varscan2
- XKR7 | c.165G>T p.R55= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs1333828816; called by muse, mutect2, varscan2
- CXXC4 | c.*17A>G | 3'UTR (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2, varscan2
- DENND2A | c.2327+20C>G | Intron (SNP) | VAF 35/364 reads (10%) | called by muse, mutect2
- DPY19L2 | c.1580+2996A>G | Intron (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- ERLIN2 | c.424+52C>T | Intron (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- HOXA2 | c.391+170G>T | Intron (SNP) | VAF 23/196 reads (12%) | called by muse, mutect2, varscan2
- IKZF1 | c.161-8288C>A | Intron (SNP) | VAF 24/404 reads (6%) | called by muse, mutect2
- KYNU | c.374-7668G>T | Intron (SNP) | VAF 25/387 reads (6%) | called by muse, mutect2
- LINC00602 | n.1012del | RNA (DEL) | VAF 20/198 reads (10%) | called by mutect2, pindel, varscan2
- MARCHF1 | c.163-70G>T | Intron (SNP) | VAF 8/121 reads (7%) | catalogued as COSV99921761; called by muse, mutect2
- MARCHF1 | c.163-71G>T | Intron (SNP) | VAF 6/118 reads (5%) | catalogued as COSV99920641; called by muse, mutect2
- MGAM | c.4618+1238G>C | Intron (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- MIR890 | n.8C>A | RNA (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- MLIP | c.613-10832G>T | Intron (SNP) | VAF 28/237 reads (12%) | called by muse, mutect2, varscan2
- MTND6P20 | chr8:46843410 T>C | 3'Flank (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- PCDHB6 | chr5:141156892 G>T | 3'Flank (SNP) | VAF 20/286 reads (7%) | called by muse, mutect2
- PDZRN3 | c.919-3744G>T | Intron (SNP) | VAF 32/294 reads (11%) | called by muse, mutect2, varscan2
- RHD | c.*258T>A | 3'UTR (SNP) | VAF 9/229 reads (4%) | called by muse, mutect2
- RIMS2 | c.2084-856C>G | Intron (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- SGSH | c.949+20C>T | Intron (SNP) | VAF 48/377 reads (13%) | catalogued as rs539024687; called by muse, mutect2, varscan2
- SRD5A1 | c.294-6934G>T | Intron (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
